Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012426-09A.3 (aliquot TARGET-15-SJMPAL012426-09A.3-01D) from TARGET case TARGET-15-SJMPAL012426, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.4 years (511 days).
Specimen TARGET-15-SJMPAL012426-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a8169d8-56b7-4035-9007-ba75a3c936d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012426-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012426-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/646f7e1e-4c9c-4756-9c3d-aab3ca7546f4

The open-access MAF lists 9 somatic variants for this specimen: 3 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLCL1 | c.2330T>C p.I777T | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1454732776; called by muse, mutect2, varscan2
- MTAP | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- TMEM132A | c.2042C>A p.S681Y (on ENST00000453848 / NM_178031.3; = p.S682Y on NM_017870.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AKR1C1 | c.666C>T p.H222= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs377035250; called by muse, mutect2, varscan2
- ARHGAP35 | c.1770C>A p.L590= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- C11orf52 | c.240C>T p.D80= | Silent (SNP) | VAF 25/177 reads (14%) | called by muse, mutect2, varscan2
- CCDC8 | c.771G>T p.V257= | Silent (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- SLC6A14 | c.606C>T p.N202= | Silent (SNP) | VAF 33/38 reads (87%) | catalogued as rs781876726, COSV64148728; called by mutect2, varscan2
- ZNF788P | n.159T>A | RNA (SNP) | VAF 10/96 reads (10%) | catalogued as rs77654018; called by muse, mutect2, varscan2
